Gene-level copy-number profile of tumor specimen TCGA-61-2614-01A from TCGA case TCGA-61-2614, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,142 days).
Specimen TCGA-61-2614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.4613360f-cf63-4836-a12b-c48cb8602417.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2614-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e7958a13-e5ce-4b3b-8702-29b5eb1653d4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 952; copy number 2: 9,931; copy number 3: 24,189; copy number 4: 7,395; copy number 5: 11,756; copy number 6: 3,608; copy number 7: 477; copy number 8: 981; copy number 9: 62; copy number 10: 250; copy number 16: 208.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2614-01A-01D-1134-01): tumor purity 0.61, ploidy 3.71, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:125,577,545–125,761,269, 3 genes (within-gene range 0–1): AL365259.1, LINC02523, HEY2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,978 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:31,588,040–40,122,168, 388 genes, copy number 9–16 (broad region; genes not listed).
- chr19:54,282,109–54,370,558, 11 genes, copy number 9: MIR4752, AC245884.5, AC245884.12, AC245884.7, AC245884.2, LILRA5, AC245884.11, VN1R104P, AC245884.6, LILRA4, LAIR1.
- chr19:57,267,211–58,605,223, 121 genes, copy number 10 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 18. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
